Gene-level copy-number profile of tumor specimen TCGA-DX-A1L0-01A from TCGA case TCGA-DX-A1L0, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 58.7 years (21,434 days).
Specimen TCGA-DX-A1L0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.9ee1c4e2-3601-4d1f-8fa3-f671c016c4d7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A1L0-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9e9613fd-97e4-4508-8db6-cf391029c3ec

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 119; copy number 1: 4,723; copy number 2: 21,881; copy number 3: 21,551; copy number 4: 7,153; copy number 5: 2,077; copy number 6: 641; copy number 7: 608; copy number 8: 424; copy number 9: 211; copy number 10: 141; copy number 11: 43; copy number 12: 3; copy number 13: 4; copy number 14: 77; copy number 16: 8; copy number 18: 2; copy number 19: 6; copy number 20: 20; copy number 21: 4; copy number 24: 22; copy number 28: 1; copy number 33: 38; copy number 35: 4; copy number 38: 11; copy number 40: 1; copy number 46: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A1L0-01A-11D-A24M-01): tumor purity 0.81, ploidy 2.88, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 62 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:242,001,209–242,160,153, 8 genes: AC093642.3, AC093642.1, AC093642.6, LINC01880, AC093642.2, LINC01881, CICP10, SEPTIN14P2.
- chr11:113,779,747–113,875,570, 8 genes (within-gene range 0–1): CLDN25, ATF4P4, AP003170.2, LRRC37A13P, USP28, AP003170.3, AP003170.1, RNU6-1107P.
- chr11:128,836,315–129,617,269, 14 genes: KCNJ1, AP000920.1, KCNJ5, C11orf45, TP53AIP1, ARHGAP32, RNU6-876P, Y_RNA, RNU6-874P, ZNF123P, BARX2, RPS27P20, AP003500.1, LINC01395.
- chr11:131,253,422–134,067,936, 27 genes (within-gene range 0–1): AP002856.2, NTM, RNU6ATAC12P, AP003025.1, AP003025.2, NTM-AS1, AP004372.1, AP000844.2, AP000844.1, NTM-IT, AP000843.1, OPCML, U6, AP003784.1, OPCML-IT2, AP004782.1, AP003972.1, OPCML-IT1, AP004606.1, LINC02743, SPATA19, AP001979.1, IGSF9B, MIR4697, LINC02730, LINC02731, AP000911.1.
- chr11:134,945,118–135,075,908, 5 genes: AP003062.2, LINC02697, AP003062.1, LINC02717, LINC02684.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,663 genes in 45 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:159,171,609–160,954,809, 83 genes, copy number 9 (broad region; genes not listed).
- chr1:166,387,727–167,220,512, 21 genes, copy number 11 (within-gene range 6–11): AL583804.1, FMO7P, LINC01675, FMO8P, FMO9P, FMO10P, RPL4P2, FMO11P, CNN2P10, POGK, TADA1, DUTP6, ILDR2, MAEL, RNA5SP65, AL158837.1, GPA33, STYXL2, AL451050.1, LINC01363, AL451050.2.
- chr1:168,540,768–169,396,540, 19 genes, copy number 7: XCL2, AL031736.1, XCL1, AL031736.2, DPT, AL135926.1, AL031275.1, LINC00626, SUMO1P2, AL135926.2, LINC00970, RPL29P7, AL031726.2, RNA5SP66, AL031726.1, ATP1B1, NME7, Z99758.1, BLZF1.
- chr1:169,662,007–169,854,080, 1 gene, copy number 10 (within-gene range 4–10): C1orf112.
- chr1:169,762,929–170,739,421, 23 genes, copy number 10: AL021940.1, METTL18, SCYL3, RN7SL333P, AL031297.1, KIFAP3, RN7SL269P, MRPS10P1, AL356475.1, SIGLEC30P, METTL11B, MIR3119-2, MIR3119-1, LINC01681, ISCUP1, LINC01142, HAUS4P1, GORAB-AS1, GORAB, AL162399.1, AL023495.1, PRRX1, Z97200.1.
- chr1:171,485,551–174,995,308, 65 genes, copy number 7–9 (within-gene range 2–9) (broad region; genes not listed).
- chr1:175,315,194–175,921,057, 4 genes, copy number 13 (within-gene range 4–13): TNR, TNR-IT1, LINC01657, LINC02803.
- chr1:180,509,380–180,951,614, 6 genes, copy number 14 (within-gene range 2–14): OVAAL, Y_RNA, XPR1, U6, LINC02816, KIAA1614.
- chr1:182,096,338–182,314,061, 1 gene, copy number 11 (within-gene range 2–11): LINC01344.
- chr1:182,182,730–182,183,096, 1 gene, copy number 11: YPEL5P1.
- chr1:184,051,651–184,335,949, 6 genes, copy number 11: TSEN15, AL158011.1, Y_RNA, Y_RNA, AL445228.1, RN7SL654P.
- chr1:185,734,391–186,988,981, 16 genes, copy number 9: HMCN1, AL133553.1, AL133553.2, PRG4, TPR, RNU6-1240P, ODR4, PDC-AS1, PDC, AL096803.3, AL096803.1, AL096803.2, AL049198.1, PTGS2, PACERR, PLA2G4A.
- chr1:189,035,961–191,228,467, 19 genes, copy number 7–16 (within-gene range 2–16): CLPTM1LP1, GAPDHP75, RNA5SP73, LINC01701, AL591504.1, AL591504.2, AL359976.1, BRINP3, AL354771.1, LINC01351, AL391645.1, LINC01720, AL139135.1, AL139135.2, AL138927.1, HNRNPA1P46, AL713866.1, AL713866.2, LINC01680.
- chr2:81,194,337–82,307,168, 10 genes, copy number 7–8: ANKRD11P1, CHMP4AP1, LINC01815, RNA5SP99, AC013262.1, RN7SL201P, AC079896.1, LYARP1, RNU6-685P, Y_RNA.
- chr3:1,595,777–2,089,211, 5 genes, copy number 7: RPL23AP38, RPL23AP39, RPL21P17, AC018814.1, RN7SKP144.
- chr3:2,110,409–2,144,241, 2 genes, copy number 7: CNTN4-AS2, AC087427.1.
- chr4:34,657,606–34,966,344, 3 genes, copy number 7: AC093689.1, AC093913.1, AC020589.1.
- chr5:24,135,160–40,755,963, 239 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).
- chr5:41,142,116–45,895,970, 74 genes, copy number 7 (broad region; genes not listed).
- chr6:80,106,647–80,557,189, 9 genes, copy number 8 (within-gene range 4–8): BCKDHB, AL359715.3, RPL17P25, AL359715.4, AL359715.1, AL359715.2, RPSAP72, AL596028.1, AL590824.1.
- chr6:91,390,313–94,447,179, 29 genes, copy number 7–10: AL080284.1, MIR4643, CASC6, MTATP6P25, MTND4LP19, MTCO1P56, RN7SL415P, AL590635.1, AL590814.1, RPL5P19, U3, AL133457.1, AL359987.1, LINC02531, U3, ATF1P1, AL138731.1, COPS5P1, EPHA7, AL591519.1, AL356094.2, AL356094.1, AL391336.2, AL391336.1, AL157378.1, AL078595.1, AL078595.3, AL078595.2, MTCYBP36.
- chr6:95,917,143–100,178,192, 47 genes, copy number 7–10 (within-gene range 6–10): AL034348.1, KRT18P50, FUT9, UFL1-AS1, RN7SL797P, UFL1, FHL5, RPS7P8, RNU4-70P, TYMSP1, AL355143.1, EEF1GP6, AL033379.1, GPR63, NDUFAF4, RN7SL509P, KLHL32, MMS22L, AL589740.1, AL080316.1, MIR2113, EIF4EBP2P3, AL590727.1, AL589826.1, AL589826.2, POU3F2, FBXL4, AL078603.1, MIR548AI, BDH2P1, FAXC, COQ3, PNISR, AL513550.1, USP45, TSTD3, Y_RNA, CCNC, AL137784.1, PRDM13, Y_RNA, MCHR2, MCHR2-AS1, NPM1P38, AL080285.2, PRDX2P4, AL080285.1.
- chr6:105,612,667–109,691,217, 90 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr6:110,020,011–143,938,471, 493 genes, copy number 7–19 (broad region; genes not listed).
- chr8:25,593,197–25,833,464, 3 genes, copy number 8: AC009623.1, AC009623.2, AC009623.3.
- chr8:27,010,486–29,064,764, 58 genes, copy number 8–9: AC067904.3, AC067904.1, MIR548H4, AC067904.2, AC090150.2, AC090150.1, STMN4, TRIM35, PTK2B, MIR6842, CHRNA2, EPHX2, GULOP, CLU, MIR6843, SCARA3, RNU6-1086P, AC013643.1, AC013643.3, MIR3622B, MIR3622A, AC013643.2, CCDC25, ESCO2, RNU6-1276P, PBK, AC104997.1, SCARA5, MIR4287, AC069113.1, AC069113.3, AC069113.2, NUGGC, ELP3, AC021678.1, AC021678.3, AC021678.2, RPL5P22, PNOC, ZNF395, FBXO16, AC025871.3, AC025871.2, RNU6-178P, AC025871.1, FZD3, MIR4288, RNA5SP259, EXTL3, EXTL3-AS1, INTS9, INTS9-AS1, AC040975.1, HMBOX1, Metazoa_SRP, HMBOX1-IT1, RNA5SP260, AC108449.2.
- chr8:29,333,064–30,572,256, 34 genes, copy number 7 (within-gene range 3–7): DUSP4, AC084262.2, AC084262.1, AC084026.2, AC084026.1, AC084026.3, RPL17P33, LINC00589, LINC02099, AC131254.1, AC131254.3, AC131254.2, LINC02209, MIR3148, MAP2K1P1, RNU6-1218P, SARAF, AC044849.1, LEPROTL1, RPS15AP24, MBOAT4, AC026979.2, DCTN6, AC026979.1, AC026979.4, AC026979.3, HSPA8P11, AC090820.1, AC090820.2, AC109329.1, PPIAP84, TUBBP1, RBPMS-AS1, RBPMS.
- chr10:58,869,184–59,551,878, 9 genes, copy number 8: RN7SKP196, LINC00844, RPLP1P10, TRAF6P1, PHYHIPL, FAM13C, AC025038.1, AL355474.1, MRPL50P4.
- chr12:57,738,013–57,846,729, 16 genes, copy number 20 (within-gene range 4–20): TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2.
- chr12:57,983,795–58,105,935, 4 genes, copy number 35–38: AC084033.2, LINC02403, AC090643.1, AC090643.2.
- chr12:58,920,639–62,600,476, 35 genes, copy number 46 (within-gene range 4–46): AC068305.2, RPS6P22, AC068305.1, AC046129.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1, AC080011.1, AC087883.2, AC087883.1, Y_RNA, AC090022.1, AC090022.2, AC090017.1, DUX4L52, AC090629.1, TAFA2, RPL21P104, KRT8P19, RPS3P6, AC078789.1, KLF17P1, USP15, MIR6125, RNU6-595P, Metazoa_SRP, MON2, AC079035.1, RNU6-399P.
- chr12:65,758,020–66,037,714, 8 genes, copy number 38: RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18.
- chr12:66,116,555–67,096,410, 16 genes, copy number 10–18 (within-gene range 4–18): LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB, GRIP1, OSBPL9P5, OSBPL9P4, AC073530.1, AC073530.2.
- chr12:67,648,338–67,670,919, 2 genes, copy number 35: DYRK2, AC078777.1.
- chr12:68,746,125–71,710,374, 60 genes, copy number 24–33: SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1.
- chr12:71,835,034–72,186,618, 5 genes, copy number 20–40: AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1.
- chr12:77,219,603–78,213,010, 4 genes, copy number 21 (within-gene range 3–21): LINC02464, NAV3, AC073591.1, AC138331.1.
- chr16:6,573,767–8,376,276, 16 genes, copy number 7: AC007223.1, AC007012.2, AC007012.1, RNU7-99P, RNU6-457P, RNU6-328P, AC022206.1, AC007222.2, AC007222.1, AC005774.2, AC005774.1, AC093515.1, AC018767.2, LINC02152, AC018767.3, AC018767.1.
- chr16:11,750,586–11,976,643, 14 genes, copy number 7: ZC3H7A, Metazoa_SRP, AC010654.1, BCAR4, RSL1D1, AC007216.4, GSPT1, AC007216.3, COX6CP1, AC007216.2, AC007216.5, NPIPB2, TNFRSF17, UBL5P4.
- chr18:75,195,113–80,247,514, 108 genes, copy number 8–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,390. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
